Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A4SD, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A4SD-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Sentinel lymph node #1, excision:
No evidence of metastasis in 3 lymph nodes (0/3).
- B. Sentinel lymph node #2, excision:
No evidence of metastasis in 3 lymph nodes (0/3).
- C. Right breast, mastectomy:
Infiltrating ductal carcinoma, grade 3, 4.3 cm greatest dimension,
surgical margins negative but close (0.4 cm, deep).

Microscopic Description:

Microscopic examination performed.

- A. B. sections of sentinel lymph nodes 1 and 2 demonstrate no
evidence in 3 lymph nodes in each specimen. The lymph nodes were
examined by multilevel sectioning with H&E staining as well as by
histochemistry for pankeratin.

C.

Invasive Carcinoma: present

Histologic type: infiltrating ductal cancer

Histologic grade:

Overall grade: 3

Architectural score: 3

Nuclear score: 3

Mitotic score: 3

Greatest dimension (pT): 4.3 cm, pT2

Specimen margins: negative, 0.4 cm to deep margin

Vessel invasion: not identified

Calcification: not identified

Ductal carcinoma in situ: not identified

Specimen

- A. Sentinel node #1
- B. Sentinel node #2
- C. Right mastectomy, arrow points up

Clinical Information

Right breast cancer

Intraoperative Consultation

AFS1-AFS3: Sentinel lymph node #1, excision - No metastasis identified
in 3 nodes.

BFS1-BFS3: Sentinel lymph node #2, excision - No metastasis identified
in 3 nodes.

Gross Description

- A. Container a is labeled with the patient's name, medical record
number and "sentinel node". The specimen container holds 3 lymph nodes
ranging in size from 1.5 x 1 x 1.5 cm to 0.6 x 0.5 x 0.4 cm. AFS 1,
AFS 2 one lymph node bisected AFS 332 lymph nodes

ICD-0-3

Carcinoma, infiltrating duct, NOS
8500/3

Site: breast, NOS C50.9

hw
10/27/12

[page 2 of 2]
B. Container B. is labeled with the patient's name, medical record number and "palpable nodule right axilla". Per Dr. this should be regarded as such libido for to. The specimen container holds 3 separate lymph nodes. Each lymph node is bisected and submitted in one block,

C. Received fresh and subsequently placed in formalin at labeled "right mastectomy" is a 27.0 cm (superior to inferior) by 26.0 cm (medial to lateral) by 6.5 cm (anterior to posterior) diffusely cauterized soft, lobulated tan-white-gold portion of fibroadipose tissue in keeping with breast. A 23.5 x 10.0 cm wrinkled brown skin ellipse with a central, 1.1 x 1.1 x 0.7 cm nipple is present along the anterior aspect. A palpable nodular mass corresponds to the lower inner quadrant and the anteroinferior surface is inked orange. The intact deep margin is inked blue and the specimen is sectioned. The after mentioned palpable mass is well-circumscribed glistening tan-white and rubbery, measuring 4.3 cm (medial to lateral) by 3.8 cm (anterior to posterior) by 3.1 cm (superior to inferior). The tumor extends to within 0.4 cm of the inked deep margin and 1 cm of the anteroinferior inked surface. Several cylindrical firm tan-white structures are associated with the lesion. A portion of the lesion and a portion of normal parenchyma are submitted for tissue procurement as requested. The remaining soft, lobulated tan gold adipose tissue with a scant amount of interspersed delicate tan-white fibrous tissue. No additional mass lesion or abnormality is identified grossly. RS 12 Summary: 1 through 3 - tumor to inked deep margin, 4 and 5 - tumor to inked anteroinferior margin, 6 - tumor to normal parenchyma, 7 - random upper outer quadrant, 8 - upper inner quadrant, 9 - lower inner quadrant, 10 - lower outer quadrant, 11 - junction of the 4 quadrants, 12 - nipple

	Yes	No
Policy		
Discrepancy		
History		
Quality Noted		
Dr. Reviewed		

10/27/12

Source: NCI Genomic Data Commons file 662e69fa-6a96-4065-a8ce-200cbeca4a09 (TCGA-A7-A4SD.563D1ED2-1A8B-4D90-BD42-AC3790D04913.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).